Somatic mutation profile of tumor specimen TCGA-22-4591-01A (aliquot TCGA-22-4591-01A-01D-1267-08) from TCGA case TCGA-22-4591, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 80.1 years (29,250 days).
Specimen TCGA-22-4591-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a59bbbd6-ee68-4d3b-bfc1-1934ee8f2e58.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-22-4591-11A (Solid Tissue Normal), aliquot TCGA-22-4591-11A-01D-1267-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2a507bf5-4172-409e-948c-ede6c01df72e

The open-access MAF lists 215 somatic variants for this specimen: 153 protein-altering or splice-affecting, 56 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 136, Silent 56, Nonsense Mutation 7, Frame Shift Del 6, Splice Site 2, In Frame Del 2, Intron 2, 5'UTR 1, 3'Flank 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVR1C | c.275G>A p.C92Y | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV54643920, COSV99694415; called by muse, varscan2
- ADAM22 | c.1184A>T p.E395V | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV55970129; called by muse, varscan2
- ADGRG7 | c.482C>T p.S161F | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV56293914; called by muse, mutect2, varscan2
- ALS2 | c.2564C>T p.A855V | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.366); catalogued as COSV51884285; called by muse, mutect2, varscan2
- ANK2 | c.11658A>C p.E3886D | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.469); catalogued as COSV52147237; called by muse, mutect2, varscan2
- ANKRD44 | c.1840G>A p.E614K | Missense Mutation (SNP) | VAF 14/236 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.687); catalogued as COSV56549849, COSV56553196; called by muse, mutect2
- AP1S1 | c.124C>T p.R42* | Nonsense Mutation (SNP) | VAF 6/68 reads (9%) | catalogued as COSV61760429; called by muse, mutect2
- APEH | c.1760C>T p.S587F | Missense Mutation (SNP) | VAF 163/450 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56532070; called by muse, mutect2, varscan2
- ARHGAP39 | c.1319G>T p.R440L | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV52767288; called by muse, mutect2, varscan2
- ASPM | c.855T>A p.N285K | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV54125022; called by muse, mutect2, varscan2
- ATRN | c.1632-2A>G p.X544_splice | Splice Site (SNP) | VAF 9/41 reads (22%) | catalogued as COSV53524124; called by muse, mutect2, varscan2
- AXL | c.248A>G p.Q83R | Missense Mutation (SNP) | VAF 44/373 reads (12%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.995); catalogued as COSV56563988; called by muse, mutect2, varscan2
- B4GALNT3 | c.1550A>T p.K517I | Missense Mutation (SNP) | VAF 53/298 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.08); catalogued as COSV56749930; called by muse, mutect2, varscan2
- BCL6 | c.218A>G p.N73S | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated (1); PolyPhen probably damaging (0.949); catalogued as rs760006045, COSV51650020; called by muse, mutect2, varscan2
- BEX4 | c.322C>A p.P108T | Missense Mutation (SNP) | VAF 226/267 reads (85%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.987); catalogued as COSV65515857; called by muse, mutect2, varscan2
- BLVRA | c.67C>T p.R23W | Missense Mutation (SNP) | VAF 121/370 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755595790, COSV55512584; called by muse, mutect2, varscan2
- C3AR1 | c.89T>A p.L30H | Missense Mutation (SNP) | VAF 98/158 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV50817537; called by muse, mutect2, varscan2
- C7orf33 | c.112C>T p.L38F | Missense Mutation (SNP) | VAF 48/210 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.53); catalogued as COSV61022760, COSV99080271; called by muse, mutect2, varscan2
- CALCR | c.308A>T p.D103V | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64006022, COSV64011396; called by muse, mutect2, varscan2
- CASS4 | c.1315G>A p.V439M | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV64385453; called by muse, mutect2, varscan2
- CASS4 | c.2348G>C p.G783A | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT tolerated (0.94); PolyPhen benign (0.038); catalogued as COSV64385457; called by muse, mutect2, varscan2
- CD7 | c.250T>C p.F84L | Missense Mutation (SNP) | VAF 153/764 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1443620452, COSV53938335; called by muse, mutect2, varscan2
- CDK19 | c.1042G>T p.G348C | Missense Mutation (SNP) | VAF 200/267 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV60447076, COSV60448991; called by muse, mutect2, varscan2
- CLTC | c.3864C>G p.N1288K | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV52245035; called by muse, mutect2, varscan2
- CNGA3 | c.1781C>A p.A594D | Missense Mutation (SNP) | VAF 99/198 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV55622331; called by muse, mutect2, varscan2
- CNGB3 | c.1063del p.R355Efs*41 | Frame Shift Del (DEL) | VAF 3/12 reads (25%) | catalogued as CM050554, COSV60684823; called by mutect2, varscan2
- CPS1 | c.2546C>A p.T849K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV51802670; called by mutect2, varscan2
- CRP | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 124/157 reads (79%) | SIFT tolerated (0.17); PolyPhen benign (0.024); catalogued as COSV54812643, COSV54814000; called by muse, mutect2, varscan2
- CSMD2 | c.7212C>G p.S2404R | Missense Mutation (SNP) | VAF 63/121 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV53882259, COSV53899079; called by muse, mutect2, varscan2
- CYP26B1 | c.1298C>T p.P433L | Missense Mutation (SNP) | VAF 164/351 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV50010803; called by muse, mutect2, varscan2
- DAND5 | c.335G>T p.R112L | Missense Mutation (SNP) | VAF 152/220 reads (69%) | SIFT deleterious (0.03); PolyPhen benign (0.155); catalogued as COSV100397174, COSV57683915; called by muse, varscan2
- DIP2A | c.4439G>A p.R1480Q | Missense Mutation (SNP) | VAF 69/177 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV59472687; called by muse, mutect2, varscan2
- DLX5 | c.331G>C p.V111L | Missense Mutation (SNP) | VAF 78/439 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV56031756; called by muse, mutect2, varscan2
- DNAH11 | c.7318G>T p.A2440S | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.077); catalogued as COSV60941179; called by muse, mutect2, varscan2
- DNAH2 | c.1207G>T p.D403Y | Missense Mutation (SNP) | VAF 68/96 reads (71%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.975); catalogued as rs1469022446, COSV50013266; called by muse, mutect2, varscan2
- DNAH2 | c.7570G>A p.E2524K | Missense Mutation (SNP) | VAF 85/120 reads (71%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV66716655; called by muse, mutect2, varscan2
- DPP9 | c.2579A>T p.Q860L (on ENST00000598800; = p.Q889L on NM_139159.5) | Missense Mutation (SNP) | VAF 22/26 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53589311; called by muse, mutect2, varscan2
- ELFN2 | c.2180G>A p.R727H | Missense Mutation (SNP) | VAF 28/204 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs1287690574, COSV68743856; called by muse, mutect2, varscan2
- ELFN2 | c.1336G>A p.D446N | Missense Mutation (SNP) | VAF 223/1475 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as COSV68743859; called by muse, mutect2, varscan2
- EMSY | c.1334A>C p.K445T | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.991); catalogued as COSV58257573; called by muse, mutect2, varscan2
- EPHA3 | c.2757G>A p.W919* | Nonsense Mutation (SNP) | VAF 71/93 reads (76%) | catalogued as COSV60694988, COSV60697263; called by muse, mutect2, varscan2
- ERICH3 | c.1312G>T p.V438L | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1254332663, COSV58599773; called by muse, varscan2
- FADD | c.81C>A p.C27* | Nonsense Mutation (SNP) | VAF 24/117 reads (21%) | catalogued as COSV100096674, COSV57228903; called by muse, mutect2, varscan2
- FAM160B1 | c.1288A>G p.M430V | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV65087287; called by muse, mutect2, varscan2
- FANCM | c.5854G>A p.E1952K | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57497487; called by muse, mutect2, varscan2
- FAT2 | c.6028G>A p.D2010N | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.721); catalogued as COSV55813942; called by muse, mutect2, varscan2
- FBXO43 | c.194G>T p.R65I | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV71053369; called by muse, mutect2, varscan2
- FPR2 | c.461T>C p.L154P | Missense Mutation (SNP) | VAF 34/226 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV60671989; called by muse, mutect2, varscan2
- FREM2 | c.9409G>C p.G3137R | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as rs1387841991, COSV54829368; called by muse, mutect2, varscan2
- FUBP3 | c.1298C>T p.P433L | Missense Mutation (SNP) | VAF 58/83 reads (70%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as COSV60512937; called by muse, mutect2, varscan2
- GAK | c.431C>T p.S144L | Missense Mutation (SNP) | VAF 86/121 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.221); catalogued as rs768962219, COSV58502921; called by muse, mutect2, varscan2
- GGA3 | c.845C>T p.A282V (on ENST00000537686 / NM_138619.4; = p.A249V on NM_014001.5) | Missense Mutation (SNP) | VAF 34/1245 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55455400; called by muse, mutect2
- IMPG2 | c.2633T>A p.V878D | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV51973794; called by muse, mutect2, varscan2
- INTS6 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.344); catalogued as COSV60876417; called by muse, mutect2, varscan2
- ITIH6 | c.2776C>A p.P926T | Missense Mutation (SNP) | VAF 35/338 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.433); catalogued as COSV54486699; called by muse, mutect2, varscan2
- KANK4 | c.2087A>T p.E696V | Missense Mutation (SNP) | VAF 66/207 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.184); catalogued as COSV62985487; called by muse, mutect2, varscan2
- KIAA1755 | c.2743G>C p.G915R | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.999); catalogued as COSV54073826; called by muse, mutect2, varscan2
- KMT5A | c.712C>T p.R238W | Missense Mutation (SNP) | VAF 56/259 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57862340; called by muse, mutect2, varscan2
- KNDC1 | c.4141G>T p.G1381C | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.039); catalogued as COSV100465233, COSV58831454; called by muse, mutect2, varscan2
- LONRF2 | c.1775G>A p.C592Y | Missense Mutation (SNP) | VAF 67/206 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1388471580, COSV66539444; called by muse, mutect2, varscan2
- LRP1 | c.8278G>T p.G2760W | Missense Mutation (SNP) | VAF 21/604 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54502639; called by muse, mutect2
- LRP2 | c.11638G>C p.D3880H | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.245); catalogued as COSV55541729; called by muse, mutect2
- LRRC4C | c.1629G>A p.M543I | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.059); catalogued as COSV53418689; called by muse, mutect2, varscan2
- LRRFIP2 | c.467A>G p.Y156C | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs765087847, COSV60866291; called by muse, mutect2, varscan2
- MAGEC1 | c.1670A>G p.D557G | Missense Mutation (SNP) | VAF 120/386 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.258); catalogued as COSV53568333; called by muse, varscan2
- MAP3K4 | c.2458A>G p.K820E | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62330247; called by muse, mutect2, varscan2
- MARK1 | c.461T>G p.M154R | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV65065717; called by muse, mutect2, varscan2
- MCF2 | c.95C>G p.P32R | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100644385, COSV58478185; called by muse, mutect2, varscan2
- MPDZ | c.1426G>A p.V476I | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs749650642, COSV59935778; called by muse, mutect2, varscan2
- MROH2B | c.4161A>C p.E1387D | Missense Mutation (SNP) | VAF 29/338 reads (9%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.797); catalogued as COSV68181183; called by muse, mutect2
- MTR | c.1055A>T p.E352V | Missense Mutation (SNP) | VAF 61/78 reads (78%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV63967126, COSV63967452; called by muse, mutect2, varscan2
- MYH1 | c.320A>G p.K107R | Missense Mutation (SNP) | VAF 51/63 reads (81%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs969846141, COSV55432043; called by muse, mutect2, varscan2
- NBEA | c.5786G>T p.C1929F | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.204); catalogued as COSV59761910; called by muse, varscan2
- NBEAL2 | c.6047A>G p.Q2016R | Missense Mutation (SNP) | VAF 304/474 reads (64%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV52754442; called by muse, mutect2
- NID2 | c.692A>G p.E231G | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV53493239; called by muse, mutect2, varscan2
- NPHP4 | c.2593A>T p.T865S | Missense Mutation (SNP) | VAF 48/82 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV65393258; called by muse, mutect2, varscan2
- NRG3 | c.278C>A p.S93Y | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64545789; called by muse, mutect2, varscan2
- OR2L13 | c.115G>A p.V39M | Missense Mutation (SNP) | VAF 55/70 reads (79%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV100813735, COSV63548492; called by muse, mutect2, varscan2
- OR52E4 | c.41T>C p.F14S | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100389159; called by mutect2, varscan2
- OR52I2 | c.890A>G p.D297G | Missense Mutation (SNP) | VAF 28/202 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.038); catalogued as COSV57044264; called by muse, mutect2, varscan2
- OR5B3 | c.352T>A p.Y118N | Missense Mutation (SNP) | VAF 37/55 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV58676411; called by muse, mutect2, varscan2
- OTUD4 | c.1270C>G p.R424G (on ENST00000447906 / NM_001366057.1; = p.R359G on NM_001102653.1) | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71381473, COSV71382293; called by muse, mutect2, varscan2
- PITX2 | c.374C>T p.T125M (on ENST00000354925 / NM_001204397.1; = p.T132M on NM_000325.6) | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60740266; called by muse, mutect2, varscan2
- PKD1L1 | c.481A>T p.T161S | Missense Mutation (SNP) | VAF 96/236 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV56958464; called by muse, mutect2, varscan2
- PLK2 | c.1070C>G p.S357* | Nonsense Mutation (SNP) | VAF 26/38 reads (68%) | catalogued as COSV57105881; called by muse, mutect2, varscan2
- PLVAP | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 50/221 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as COSV53083662; called by muse, mutect2, varscan2
- PRDM9 | c.2573A>T p.K858M | Missense Mutation (SNP) | VAF 51/655 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57002832; called by muse, mutect2
- PRPF40A | c.215G>T p.R72L | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.027); catalogued as rs749241784, COSV100423900; called by muse, mutect2, varscan2
- PSMD12 | c.342A>T p.E114D | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV62065132; called by muse, mutect2, varscan2
- REM1 | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 125/536 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.175); catalogued as COSV52426892; called by muse, mutect2, varscan2
- RIC8A | c.1103A>T p.E368V (on ENST00000526104 / NM_001286134.1; = p.E374V on NM_021932.5) | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57342085; called by muse, mutect2, varscan2
- RNF145 | c.1498C>G p.L500V (on ENST00000424310 / NM_001199383.2; = p.L528V on NM_144726.2) | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.617); catalogued as COSV50864409; called by muse, mutect2, varscan2
- RNF17 | c.2566C>A p.Q856K | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.53); catalogued as COSV55034248; called by muse, mutect2
- RNFT1 | c.136C>A p.H46N | Missense Mutation (SNP) | VAF 48/307 reads (16%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.549); catalogued as COSV59869252; called by muse, mutect2, varscan2
- ROBO2 | c.1436G>A p.R479Q | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.71); PolyPhen benign (0.094); catalogued as rs746150931, COSV100167830, COSV59898161; called by muse, mutect2, varscan2
- RPL37 | c.3+1G>A p.X1_splice | Splice Site (SNP) | VAF 37/350 reads (11%) | catalogued as COSV99947528; called by muse, mutect2, varscan2
- RSPH6A | c.817G>T p.E273* | Nonsense Mutation (SNP) | VAF 174/612 reads (28%) | catalogued as COSV55570108; called by muse, mutect2, varscan2
- RUBCNL | c.1097C>A p.S366Y | Missense Mutation (SNP) | VAF 19/26 reads (73%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); catalogued as COSV59785503; called by muse, mutect2, varscan2
- RYR2 | c.4870C>A p.P1624T | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.814); catalogued as COSV63663886; called by muse, mutect2, varscan2
- RYR2 | c.4871C>A p.P1624H | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV63663890; called by muse, mutect2, varscan2
- SACS | c.5642G>C p.G1881A | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV66534877; called by muse, mutect2, varscan2
- SALL2 | c.1895A>T p.Q632L | Missense Mutation (SNP) | VAF 67/338 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58102095; called by muse, mutect2, varscan2
- SALL4 | c.1513G>A p.G505S | Missense Mutation (SNP) | VAF 167/1437 reads (12%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs200920825, COSV53849939; called by muse, mutect2, varscan2
- SCG3 | c.10C>T p.L4F | Missense Mutation (SNP) | VAF 38/60 reads (63%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as COSV55020080, COSV99591163; called by muse, mutect2, varscan2
- SCN1A | c.1734A>T p.R578S | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV57660917; called by muse, mutect2, varscan2
- SEC22A | c.193T>C p.S65P | Missense Mutation (SNP) | VAF 43/157 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV59371102; called by muse, mutect2, varscan2
- SELE | c.936T>A p.N312K | Missense Mutation (SNP) | VAF 20/24 reads (83%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); catalogued as COSV60974007; called by muse, varscan2
- SGMS1 | c.602A>T p.Q201L | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated (0.31); PolyPhen benign (0.074); catalogued as COSV62369355; called by muse, mutect2, varscan2
- SGPP1 | c.656T>C p.M219T | Missense Mutation (SNP) | VAF 122/264 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.199); catalogued as COSV55974605; called by muse, mutect2, varscan2
- SOX1 | c.21G>C p.E7D | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as COSV58378444; called by muse, mutect2, varscan2
- SOX14 | c.11C>A p.P4H | Missense Mutation (SNP) | VAF 60/522 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV60162357; called by muse, mutect2, varscan2
- SOX7 | c.377G>C p.C126S | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.554); catalogued as COSV58730275; called by muse, mutect2, varscan2
- SPACA3 | c.479A>T p.N160I | Missense Mutation (SNP) | VAF 97/242 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52190394; called by muse, mutect2, varscan2
- SPAST | c.784G>A p.G262S | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT tolerated (0.36); PolyPhen benign (0.017); catalogued as COSV59512790; called by muse, mutect2, varscan2
- SPRYD3 | c.359C>G p.A120G | Missense Mutation (SNP) | VAF 87/404 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as COSV56852425; called by muse, mutect2, varscan2
- STEAP1 | c.637G>A p.V213I | Missense Mutation (SNP) | VAF 15/157 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51880978; called by muse, mutect2, varscan2
- SUCNR1 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 49/156 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.265); catalogued as COSV62911861; called by muse, mutect2, varscan2
- SUZ12 | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV59498154; called by muse, mutect2, varscan2
- TAF1 | c.2794G>A p.G932R (on ENST00000373790 / NM_138923.4; = p.G953R on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52107816, COSV99034758; called by muse, mutect2, varscan2
- TBX2 | c.868A>T p.N290Y | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV53597618; called by muse, varscan2
- TBX21 | c.677C>G p.P226R | Missense Mutation (SNP) | VAF 34/498 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51595103; called by muse, mutect2
- TENM3 | c.29G>T p.C10F | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.597); catalogued as COSV69299828; called by muse, mutect2, varscan2
- TEX12 | c.343A>G p.T115A | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.5); PolyPhen benign (0.037); catalogued as COSV54783614; called by muse, mutect2, varscan2
- TKTL2 | c.1223C>A p.A408D | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54917479; called by muse, mutect2, varscan2
- TLX1 | c.629G>T p.R210L | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV64622314, COSV64622460; called by muse, mutect2, varscan2
- TNRC6C | c.1012G>A p.G338S | Missense Mutation (SNP) | VAF 58/344 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs781403556, COSV56940668; called by muse, mutect2, varscan2
- TSPOAP1 | c.2776A>G p.S926G | Missense Mutation (SNP) | VAF 600/815 reads (74%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52104377; called by muse, mutect2, varscan2
- UBN1 | c.3094C>T p.P1032S | Missense Mutation (SNP) | VAF 54/1094 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as COSV52165852; called by muse, mutect2
- UGGT2 | c.344A>T p.Y115F | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.081); catalogued as COSV65025031; called by muse, mutect2, varscan2
- VSTM2A | c.335T>C p.L112P | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56492337; called by muse, mutect2, varscan2
- WAPL | c.793G>C p.D265H | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.188); catalogued as COSV53932529; called by muse, mutect2, varscan2
- WARS1 | c.1181G>A p.C394Y | Missense Mutation (SNP) | VAF 216/1028 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.792); catalogued as COSV59924436; called by muse, mutect2, varscan2
- WDFY3 | c.2973T>G p.D991E | Missense Mutation (SNP) | VAF 73/292 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.956); catalogued as COSV55693977; called by muse, mutect2, varscan2
- ZNF208 | c.3089A>T p.K1030I | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV68100971; called by muse, mutect2, varscan2
- ZNF257 | c.149C>A p.P50Q | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.285); catalogued as COSV71306232; called by muse, mutect2, varscan2
- ZNF417 | c.31del p.Q11Sfs*5 | Frame Shift Del (DEL) | VAF 22/93 reads (24%) | catalogued as COSV100364066; called by mutect2, varscan2
- ZNF438 | c.256G>T p.A86S | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.223); catalogued as COSV59192421; called by muse, mutect2, varscan2
- ZNF473 | c.847C>T p.Q283* | Nonsense Mutation (SNP) | VAF 39/174 reads (22%) | catalogued as COSV54522121; called by muse, mutect2, varscan2
- ZNF560 | c.1535G>T p.G512V | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56865546; called by muse, mutect2, varscan2
- ZNF567 | c.913G>T p.G305* (on ENST00000536254 / NM_001322913.1; = p.G274* on NM_152603.5 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 7/17 reads (41%) | catalogued as COSV62444300; called by muse, mutect2
- ZNF567 | c.914G>T p.G305V (on ENST00000536254 / NM_001322913.1; = p.G274V on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62444307; called by muse, mutect2
- ZNF787 | c.79G>T p.V27L | Missense Mutation (SNP) | VAF 102/224 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV54417664, COSV54418600; called by muse, mutect2, varscan2
- FAM83F | c.1416del p.K473Rfs*26 | Frame Shift Del (DEL) | VAF 56/430 reads (13%) | called by mutect2, varscan2
- FRG2C | c.780T>A p.H260Q | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, varscan2
- GDF10 | c.774C>A p.S258R | Missense Mutation (SNP) | VAF 204/229 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGHD1-20 | c.14C>G p.T5R | Missense Mutation (SNP) | VAF 76/219 reads (35%) | PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNU1 | c.2321del p.Y774Sfs*18 | Frame Shift Del (DEL) | VAF 2/12 reads (17%) | called by mutect2, varscan2
- OR51A7 | c.759del p.I254Sfs*19 | Frame Shift Del (DEL) | VAF 21/184 reads (11%) | called by mutect2, pindel, varscan2
- PUS7 | c.1437_1445del p.Q480_Y482del | In Frame Del (DEL) | VAF 184/483 reads (38%) | called by mutect2, pindel, varscan2
- TRGV3 | c.197T>A p.L66Q | Missense Mutation (SNP) | VAF 59/166 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- VEZF1 | c.1466_1490del p.P489Lfs*4 | Frame Shift Del (DEL) | VAF 50/108 reads (46%) | called by mutect2, varscan2
- ZNF608 | c.1047_1061del p.V350_T354del | In Frame Del (DEL) | VAF 11/37 reads (30%) | called by mutect2, pindel, varscan2
- ZNF84 | c.1309G>C p.G437R | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- ABCA9 | c.282G>T p.V94= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV60620835; called by muse, mutect2, varscan2
- ADAMTS10 | c.153G>T p.G51= | Silent (SNP) | VAF 44/53 reads (83%) | catalogued as COSV54352188; called by muse, mutect2, varscan2
- AL441992.2 | c.1278C>A p.I426= | Silent (SNP) | VAF 106/309 reads (34%) | catalogued as COSV56912434; called by muse, mutect2, varscan2
- ANK3 | c.8562A>G p.T2854= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as rs762063080, COSV55045151; called by muse, mutect2, varscan2
- ANKRD50 | c.687A>G p.L229= | Silent (SNP) | VAF 27/95 reads (28%) | catalogued as rs902874526, COSV72385074; called by muse, mutect2, varscan2
- APOH | c.846T>A p.I282= | Silent (SNP) | VAF 20/202 reads (10%) | catalogued as COSV52771480; called by muse, mutect2, varscan2
- ASPM | c.5769A>G p.A1923= | Silent (SNP) | VAF 27/36 reads (75%) | catalogued as rs1241825346, COSV54125013; called by muse, mutect2, varscan2
- ATPAF2 | c.57G>A p.P19= | Silent (SNP) | VAF 56/70 reads (80%) | catalogued as COSV52008116; called by muse, varscan2
- BRINP3 | c.591C>T p.H197= | Silent (SNP) | VAF 141/194 reads (73%) | catalogued as COSV66514301; called by muse, mutect2, varscan2
- BRSK2 | c.936C>T p.F312= | Silent (SNP) | VAF 17/108 reads (16%) | catalogued as rs199880359, COSV57540290, COSV57540594; called by muse, mutect2, varscan2
- CABYR | c.168A>G p.K56= | Silent (SNP) | VAF 16/24 reads (67%) | catalogued as COSV59110240; called by muse, mutect2, varscan2
- CBLN1 | c.54G>T p.P18= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV54653384, COSV54653407; called by muse, mutect2, varscan2
- CBLN4 | c.276C>T p.I92= | Silent (SNP) | VAF 319/2313 reads (14%) | catalogued as rs1407962921, COSV50352110; called by muse, mutect2, varscan2
- CDH23 | c.6954G>A p.V2318= | Silent (SNP) | VAF 92/169 reads (54%) | catalogued as COSV56449290; called by muse, mutect2, varscan2
- CRAT | c.1506C>T p.A502= | Silent (SNP) | VAF 10/16 reads (63%) | catalogued as COSV58876081; called by muse, mutect2, varscan2
- CSMD1 | c.9933G>C p.G3311= (on ENST00000520002; = p.G3310= on NM_033225.6) | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV59284285; called by muse, mutect2
- CXXC4 | c.639C>T p.C213= | Silent (SNP) | VAF 48/1139 reads (4%) | catalogued as COSV67295847; called by muse, mutect2
- DCT | c.198C>T p.A66= | Silent (SNP) | VAF 34/120 reads (28%) | catalogued as rs375795787; called by muse, mutect2, varscan2
- DLAT | c.1212T>A p.V404= | Silent (SNP) | VAF 216/326 reads (66%) | catalogued as rs868920188, COSV54769106; called by muse, mutect2, varscan2
- EP400 | c.8652C>T p.S2884= | Silent (SNP) | VAF 55/206 reads (27%) | catalogued as rs755315336, COSV57763554; called by muse, mutect2, varscan2
- EPHA6 | c.2352A>G p.P784= (on ENST00000389672 / NM_001080448.3; = p.P176= on NM_173655.4) | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV101061067; called by mutect2, varscan2
- EPX | c.255A>G p.T85= | Silent (SNP) | VAF 603/842 reads (72%) | catalogued as COSV56595027; called by muse, varscan2
- ETV3L | c.927G>T p.G309= | Silent (SNP) | VAF 126/152 reads (83%) | catalogued as COSV71900973; called by muse, mutect2, varscan2
- FAT2 | c.64C>T p.L22= | Silent (SNP) | VAF 85/122 reads (70%) | catalogued as COSV55813949, COSV55827327; called by muse, mutect2, varscan2
- FOXB1 | c.846C>A p.T282= | Silent (SNP) | VAF 24/32 reads (75%) | catalogued as rs765818875, COSV68525660; called by muse, mutect2, varscan2
- GCM2 | c.519C>T p.S173= | Silent (SNP) | VAF 45/206 reads (22%) | catalogued as rs781711581, COSV65275104, COSV65275646; called by muse, mutect2, varscan2
- IGSF21 | c.1146G>T p.G382= | Silent (SNP) | VAF 105/213 reads (49%) | catalogued as COSV52125921; called by muse, mutect2, varscan2
- KCNQ4 | c.450G>A p.R150= | Silent (SNP) | VAF 72/339 reads (21%) | catalogued as COSV61272068; called by muse, mutect2, varscan2
- LRIG3 | c.1677G>T p.V559= | Silent (SNP) | VAF 45/55 reads (82%) | catalogued as COSV57861037; called by muse, mutect2, varscan2
- MAPKAPK3 | c.462C>T p.I154= | Silent (SNP) | VAF 82/104 reads (79%) | catalogued as COSV63596832; called by muse, mutect2, varscan2
- MGA | c.7833A>G p.L2611= (on ENST00000219905 / NM_001164273.1; = p.L2402= on NM_001080541.2) | Silent (SNP) | VAF 44/145 reads (30%) | catalogued as rs1278179928, COSV54949273; called by muse, mutect2, varscan2
- MORC1 | c.2061T>C p.T687= | Silent (SNP) | VAF 48/169 reads (28%) | catalogued as COSV51714613; called by muse, mutect2, varscan2
- NBPF3 | c.1029G>A p.Q343= | Silent (SNP) | VAF 43/162 reads (27%) | catalogued as COSV59056857; called by muse, mutect2, varscan2
- NOD2 | c.1956G>A p.S652= | Silent (SNP) | VAF 59/217 reads (27%) | catalogued as rs141355588; ClinVar: likely benign; called by muse, mutect2, varscan2
- OR11H12 | c.120C>A p.I40= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as rs1253905762, COSV73543477; called by mutect2, varscan2
- OR5B2 | c.165C>A p.T55= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV56907599; called by muse, mutect2, varscan2
- OR5L1 | c.699C>A p.G233= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as COSV61732858; called by muse, mutect2, varscan2
- PDZD2 | c.4449G>C p.P1483= | Silent (SNP) | VAF 24/213 reads (11%) | catalogued as COSV56851383, COSV56851510; called by muse, mutect2, varscan2
- PLVAP | c.843C>T p.S281= | Silent (SNP) | VAF 49/217 reads (23%) | catalogued as COSV53083647; called by muse, mutect2, varscan2
- PPARA | c.273C>T p.D91= | Silent (SNP) | VAF 34/316 reads (11%) | catalogued as rs895647814, COSV53077115, COSV53077366; called by muse, mutect2, varscan2
- RHBDF2 | c.465G>A p.K155= | Silent (SNP) | VAF 65/323 reads (20%) | catalogued as COSV57419493; called by muse, mutect2, varscan2
- RNFT1 | c.135G>A p.L45= | Silent (SNP) | VAF 48/301 reads (16%) | catalogued as COSV59869265; called by muse, mutect2, varscan2
- RXFP2 | c.213T>C p.C71= | Silent (SNP) | VAF 8/163 reads (5%) | catalogued as COSV53633241; called by muse, mutect2
- SALL2 | c.1071G>A p.L357= | Silent (SNP) | VAF 89/252 reads (35%) | catalogued as rs1315778854, COSV58102102; called by muse, mutect2, varscan2
- SBF2 | c.1245T>C p.G415= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV56291953; called by muse, varscan2
- SCRIB | c.4470C>A p.L1490= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV57582496; called by muse, mutect2, varscan2
- SEC14L5 | c.45G>A p.P15= | Silent (SNP) | VAF 150/194 reads (77%) | catalogued as rs541090079, COSV52036485; called by muse, mutect2, varscan2
- SYNM | c.2097C>T p.S699= | Silent (SNP) | VAF 9/129 reads (7%) | catalogued as rs372872812, COSV100152465; called by muse, mutect2
- TAF1C | c.42C>T p.T14= | Silent (SNP) | VAF 31/120 reads (26%) | catalogued as rs141321804; called by muse, mutect2, varscan2
- TP53 | c.207T>C p.A69= | Silent (SNP) | VAF 421/565 reads (75%) | catalogued as rs775185978, COSV52742379; ClinVar: likely benign; called by muse, mutect2, varscan2
- UBN1 | c.2523C>A p.L841= | Silent (SNP) | VAF 224/281 reads (80%) | catalogued as COSV52165840; called by muse, mutect2, varscan2
- USP16 | c.207T>C p.P69= | Silent (SNP) | VAF 58/73 reads (79%) | catalogued as COSV57624016; called by muse, mutect2, varscan2
- VPS13B | c.6501T>C p.L2167= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV62133853; called by muse, mutect2, varscan2
- VSX2 | c.528T>C p.Y176= | Silent (SNP) | VAF 75/156 reads (48%) | catalogued as COSV56216622; called by muse, mutect2, varscan2
- ZNF521 | c.1092A>T p.S364= | Silent (SNP) | VAF 6/73 reads (8%) | catalogued as COSV100831818, COSV64122769; called by muse, mutect2
- ZNF701 | c.903A>C p.I301= (on ENST00000301093; = p.I235= on NM_018260.3) | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV56523270; called by muse, mutect2, varscan2
- BAX | c.474+67C>T | Intron (SNP) | VAF 40/171 reads (23%) | catalogued as COSV99508970; called by muse, mutect2, varscan2
- GUF1 | c.-1C>T | 5'UTR (SNP) | VAF 12/45 reads (27%) | catalogued as rs1290093486, COSV99877074; called by muse, mutect2, varscan2
- HERC2P3 | n.1724C>G | RNA (SNP) | VAF 15/159 reads (9%) | called by muse, mutect2, varscan2
- MLST8 | c.*2C>T | 3'UTR (SNP) | VAF 604/729 reads (83%) | catalogued as rs559590456, COSV100063218; called by muse, mutect2, varscan2
- OR52A4P | chr11:5120867 C>T | 3'Flank (SNP) | VAF 13/30 reads (43%) | catalogued as rs778512643; called by muse, mutect2, varscan2
- TP53AIP1 | c.141+48C>A | Intron (SNP) | VAF 62/439 reads (14%) | catalogued as COSV101513087; called by mutect2, varscan2
